Gene-level copy-number profile of tumor specimen C3N-00199-02 from CPTAC case C3N-00199, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 65.7 years (24,010 days).
Specimen C3N-00199-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6af50959-9fe5-4181-a616-bbaf1bc0f6fb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00199-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/b7cccf53-c439-46e7-973c-2a2f6fcb9331

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 546; copy number 1: 284; copy number 2: 3,841; copy number 3: 7,527; copy number 4: 23,078; copy number 5: 9,732; copy number 6: 4,158; copy number 7: 1,301; copy number 8: 4,023; copy number 9: 2,375; copy number 10: 1,539; copy number 11: 5; copy number 12: 215; copy number 13: 155; copy number 14: 100; copy number 15: 15; copy number 53: 3; copy number 77: 5; copy number 108: 7.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,812 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–210,676,296, 1,727 genes, copy number 9–13 (broad region; genes not listed).
- chr4:15,004,942–15,427,914, 1 gene, copy number 9 (within-gene range 6–9): C1QTNF7-AS1.
- chr4:15,339,818–15,743,582, 11 genes, copy number 9: C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1.
- chr7:45,268,681–62,275,678, 241 genes, copy number 10–15 (broad region; genes not listed).
- chr9:13,386,130–16,870,843, 44 genes, copy number 9–15 (within-gene range 4–15): AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1.
- chr9:25,088,811–30,935,977, 49 genes, copy number 9: RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4.
- chr10:38,452,987–38,783,108, 10 genes, copy number 9: CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:47,908,064–49,539,538, 36 genes, copy number 9: AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4, FAM170B-AS1, FAM170B, TMEM273, C10orf71-AS1, C10orf71, DRGX, AL138760.1, ERCC6.
- chr14:18,333,726–18,419,273, 4 genes, copy number 11: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:102,341,102–106,879,812, 318 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr16:11,555–34,163,110, 1,326 genes, copy number 9 (broad region; genes not listed).
- chr19:29,205,320–29,824,312, 15 genes, copy number 53–108: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1.
- chr20:63,895,126–64,327,972, 30 genes, copy number 10: DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
